CGCI case HTMCP-02-07-01066 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5816db3-dca7-4005-8683-96f92475fbd6

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Non-small cell carcinoma: ICD-O-3 morphology code: 8046/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 52.0 years (19,006 days); Year of diagnosis: 2018; Method of diagnosis: Fine Needle Aspiration; AJCC clinical T: T3; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,078 days (3.0 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 15.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS; Surgery, NOS.

Follow-up (6 entries)
- Days to follow up: 0 days; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 356 days; Disease response: Tumor Free.
- Days to follow up: 666 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,049 days (2.9 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 1,049 days (2.9 years).
- Days to follow up: 1,078 days (3.0 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -4,369.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day -4,369: Comorbidities: HIV/AIDS.
- Day -4,369: Risk factors: HIV/AIDS.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Weight: 73.5 kg; Height: 182.9 cm; BMI: 22; CD4 count: 720; Haart treatment indicator: Yes.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 356: Nadir CD4 count: 463.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 17; Tobacco smoking quit year: 2019.

Biospecimens (3 samples)
- Sample HTMCP-02-07-01066-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-07-01066-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-07-01066-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Non-Small Cell Lung Cancer (NOS); Tumor status: Tumor free; Tobacco smoking age started: 18; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Lost to follow-up: No; Tobacco smoking history indicator: 4.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: Year of HIV diagnosis: 2006; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: Hepatitis B Virus.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Fine needle aspiration biopsy.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event site: Lung; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-07-01066-01A-01D-14909:
- % tumour top: 50
- % tumour bottom: 50

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-07-01066-01A-01R-14909:
- % tumour top: 50
- % tumour bottom: 50
